Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZS, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZS-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

1

DOB:

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

(A) CONFIRM PARATHYROID:

Parathyroid tissue, no tumor present.

ICD-0-3

Carcinoma, papillary, thyroid

8260/3

(B) THYROID AND LEVEL 6 CONTENTS
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Isthmus

Multi-focal: No

Size = 1.6 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Present

Resection Margins: Negative

Background Thyroid: Chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN 10 OF 17 LYMPH NODES

Location: Periglandular

Extracapsular extension: Absent

Thymus, no tumor present.

Site: thyroid, NOS C73.9

hw

6/17/12

(C) RIGHT LEVEL 4:

METASTATIC PAPILLARY THYROID CARCINOMA IN 1 OF 5 LYMPH NODES

Extracapsular extension: Absent

(D) LEVEL 4 AND 5 B

METASTATIC PAPILLARY THYROID CARCINOMA IN 2 OF 18 LYMPH NODES

Extracapsular extension: Absent

GROSS DESCRIPTION

(A) CONFIRM PARATHYROID – A fragment of tan-red soft tissue, measuring 0.3 x 0.2 x 0.2 cm. Touch preparation has been performed and the entire specimen is submitted for frozen section.

SECTION CODE: A, the entire specimen, for frozen section.

*FS/DX: PARATHYROID TISSUE PRESENT.

(B) THYROID AND LEVEL 6 CONTENTS - The specimen has an overall measurement of 7.0 x 5.0 x 1.5 cm and consists of a thyroid, including right lobe (5.5 x 2.2 x 1.1 cm), left lobe, (3.8 x 2.2 x 1.1 cm), a prominent isthmus (4.0 x 3.5 x 0.8 cm) and fibroadipose tissue (4.0 x 3.0 x 1.5 cm) attached to the inferior aspect of the thyroid (level 6 contents).

A dominant nodule (1.6 x 1.1 x 0.7 cm) is found in the lower pole of the isthmus adjacent to the left lobe. The nodule is composed of white-yellow homogeneous tissue and is well circumscribed.

Page 1 of 2

Surgical Pathology Report

File under: Pathology

[page 2 of 2]
Surgical Pathology Report

DOB:
Physician

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession

The right lobe of the thyroid is unremarkable and composed of homogeneous red-brown tissue. The left lobe of the thyroid is unremarkable and composed of homogeneous red-brown tissue. Attached to the lower portion of the isthmus, a piece of adipose tissue admixed with several lymph nodes is identified. This area is dissected for lymph nodes.

SECTION CODE: B1-B3, dominant nodule from the isthmus from medial to lateral; B4, left lobule, representative sections, lower pole; B5, left lobule, representative sections, upper pole; B6, lower pole, right lobule; B7, upper pole, right lobule, representative sections; B8, four possible lymph nodes; B9, four possible lymph nodes; B10, one lymph node; B11, two lymph nodes; B12, one lymph node; B13, one lymph node; B14, one lymph node bisected; B15, one lymph node bisected; B16, one lymph node bisected.

(C) RIGHT LEVEL 4 – A single fragment of fibrofatty tissue measuring 2.0 x 1.5 x 0.8 cm. Dissection reveals multiple possible lymph nodes ranging from 0.5 up to 1.2 cm in greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: C1, four possible lymph nodes; C2, one sectioned possible lymph node.

(D) LEVEL 4 AND 5 B – A single fragment of fatty tissue measuring 3.8 x 3.0 x 0.8 cm. Multiple possible lymph nodes are identified ranging from 0.4 up to 1.2 cm in greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: D1, five possible lymph nodes; D2, five possible lymph nodes; D3, five possible lymph nodes; D4, three possible lymph nodes; D5, one bisected possible lymph node.

CLINICAL HISTORY

Papillary thyroid cancer.

SNOMED CODES

T-C4200, M-80506, T-C4200, M-80506, T-B6000, M-80503, M-B0630, T-C4200, M-80506,

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Surgical Pathology Report		Page 2 of 2
File under: Pathology		

Source: NCI Genomic Data Commons file 04d1ebc1-a6a8-4d77-be73-8249533869bb (TCGA-EL-A3ZS.28FCCF82-C2A7-462A-8590-E873CC86696A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).